Somatic mutation profile of tumor specimen TARGET-20-PAMYAS-04A (aliquot TARGET-20-PAMYAS-04A-01D) from TARGET case TARGET-20-PAMYAS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,972 days).
Specimen TARGET-20-PAMYAS-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 941650e7-dd1a-430f-b06c-92fa16c64b04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAMYAS-14A (Bone Marrow Normal), aliquot TARGET-20-PAMYAS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ba674a3-0659-4385-8cb9-3ddfd935a2fa

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 14, Silent 7, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TET2 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | hotspot (GDC flag); catalogued as rs572712965, COSV54395664; called by muse, mutect2, varscan2
- ABCC9 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs202103893, COSV53973931; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BDKRB2 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as rs200683377; called by muse, mutect2, varscan2
- CTSA | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs199916179, COSV51944460; called by muse, mutect2, varscan2
- GBF1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs773687708, COSV64148788; called by muse, mutect2, varscan2
- HYDIN | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 95/313 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753825612, COSV55482951; called by muse, mutect2, varscan2
- LNPEP | c.2395C>T p.L799F | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV51477409; called by muse, mutect2, varscan2
- LRIT2 | c.1528del p.T510Pfs*26 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs1416609111, COSV60562681; called by mutect2, varscan2
- OR2D3 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100505129; called by muse, mutect2, varscan2
- RREB1 | c.4849A>G p.S1617G | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58565053; called by muse, mutect2, varscan2
- SLC35C1 | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV58480843; called by muse, mutect2, varscan2
- TNS2 | c.1627C>T p.R543C (on ENST00000314250 / NM_170754.4; = p.R553C on NM_015319.2) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as rs746134660; called by muse, mutect2
- TRPC4 | c.2083C>T p.R695* (on ENST00000379705 / NM_016179.4; = p.R700* on NM_003306.3) | Nonsense Mutation (SNP) | VAF 110/351 reads (31%) | catalogued as rs762198056, COSV59019635; called by muse, mutect2, varscan2
- USP9X | c.6358_6359insGGCCT p.I2120Rfs*3 | Frame Shift Ins (INS) | VAF 119/270 reads (44%) | catalogued as COSV61074858; called by mutect2, pindel, varscan2
- FIGN | c.1106C>A p.A369D | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KCNMA1 | c.1977A>T p.L659F | Missense Mutation (SNP) | VAF 108/378 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- PCDH11Y | c.381A>T p.K127N (on ENST00000400457 / NM_032973.2; = p.K116N on NM_032971.3) | Missense Mutation (SNP) | VAF 241/436 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SEMA7A | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ATP8B1 | c.2913C>T p.F971= | Silent (SNP) | VAF 62/232 reads (27%) | called by muse, mutect2, varscan2
- CARD11 | c.2808C>T p.D936= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs375569843; called by muse, mutect2, varscan2
- CEP128 | c.2133C>T p.H711= | Silent (SNP) | VAF 69/206 reads (33%) | catalogued as rs371329400; called by muse, mutect2, varscan2
- ENPP6 | c.219C>A p.P73= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as COSV99699171; called by muse, mutect2, varscan2
- MCC | c.1152C>T p.H384= | Silent (SNP) | VAF 124/488 reads (25%) | catalogued as rs747470968; called by muse, mutect2, varscan2
- SLC16A9 | c.1188C>T p.V396= | Silent (SNP) | VAF 51/210 reads (24%) | called by muse, mutect2, varscan2
- SPHKAP | c.720A>T p.S240= | Silent (SNP) | VAF 50/151 reads (33%) | called by muse, mutect2, varscan2
